Somatic mutation profile of tumor specimen 0DTP5B from CCDI case PBCJRT, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Pilocytic astrocytoma; Tissue or organ of origin: Cerebrum; Age at diagnosis: 14.4 years (5,246 days).
Specimen 0DTP5B: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ab31e504-64c6-4a2d-8287-a4b88383641c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DTP5D (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/18e08bce-dc69-4219-9220-d1715d9b518f

The open-access MAF lists 6 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, Intron 2, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ZNF575 | c.346G>A p.A116T | Missense Mutation (SNP) | VAF 152/664 reads (23%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.55); catalogued as rs866041359; called by muse, mutect2, varscan2
- CASP14 | c.124A>T p.M42L | Missense Mutation (SNP) | VAF 82/1086 reads (8%) | SIFT tolerated (1); PolyPhen probably damaging (0.921); called by muse, mutect2
- ZNF510 | c.742C>G p.Q248E | Missense Mutation (SNP) | VAF 66/1592 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.014); called by muse, mutect2
- SLCO1B1 | c.657T>A p.G219= | Silent (SNP) | VAF 90/2150 reads (4%) | called by muse, mutect2
- ABCA3 | c.613+94G>C | Intron (SNP) | VAF 7/169 reads (4%) | catalogued as rs1262556378; called by muse, mutect2
- HOATZ | c.453-43C>T | Intron (SNP) | VAF 32/514 reads (6%) | catalogued as rs765940978, COSV60441416; called by muse, mutect2
